HCMI case HCM-BROD-0221-C43 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/95228cfd-9465-486e-8202-b27f834433c2

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1938; Vital status: Dead; Days to death: 277 days.

Diagnoses (2)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C43.9; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 77.5 years (28,304 days); AJCC staging edition: 7th; AJCC clinical stage: Stage IV; AJCC pathologic T: T4b; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IV; Prior malignancy: yes; Prior treatment: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Pembrolizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 223 days; Days to treatment end: 277 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Chemotherapy, for residual disease; adjuvant Hormone Therapy, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/6; ICD-10 code: C79.2; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin, NOS; Classification of tumor: metastasis; Age at diagnosis: 77.7 years (28,364 days); Days to diagnosis: 60 days.
   Pathology details: Breslow thickness category: >4.0 mm; Lymphatic invasion present: No; Vascular invasion present: No.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day 231, day 277.

Molecular and laboratory tests
- BRAF mutation, nos: Negative.
- KIT mutation, nos: Negative.
- NRAS mutation, nos: Positive; Amino-acid change: Q61R.
- TP53 mutation, nos: Positive; Amino-acid change: G245D.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 60.8 kg; Height: 172.7 cm; BMI: 20.4.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample HCM-BROD-0221-C43-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample HCM-BROD-0221-C43-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 6.
